CPTAC case C3L-00104 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d42636dd-728c-45a4-b953-db165a30c761

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Dead; Days to death: 129 days; Year of death: 2016; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 58.0 years (21,197 days); Year of diagnosis: 2016; Last known disease status: With tumor; Days to last known disease status: 129 days; Progression or recurrence: no; Days to last follow up: 128 days.
   Pathology details: Greatest tumor dimension: 1 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 128 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 101 days.

Other clinical attributes
- Weight: 115 kg; Height: 188 cm; BMI: 32.54.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 35; Cigarettes per day: 20; Tobacco smoking onset year: 1971; Tobacco smoking quit year: 2006; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 35.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00104-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 145 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00104-21: Section location: Frontal Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-00104-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
